Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACM1, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACM1-TTP1-A (Primary Tumor).

[page 1 of 2]
Submissions:

- A) lower lobe of the left lung, removal
- B) lower paratracheal lymph nodes, removal
- C) under aortic lymph nodes, removal
- D) under carinal lymph nodes, removal
- E) paraesophageal lymph nodes, removal
- F) the pulmonary ligament lymph nodes, removal
- G) hilar lymph node, removal
- H) interlobar lymph nodes, removal

CDDP-YP-ACM1-01-PR

Macroscopic report:

A) Lung lobe of cm 16x8x3. Serous visceral is smooth and shiny, showing a retraction which corresponds, to the cut, a neoplasm of cm 3.5 cutting cm diameter, grayish white, to polylobate margins, elastic hard consistency to the cut. The neoplasm is 2 cm from the bronchial resection margin. Remaining parenchyma of emphysematous appearance.

Isolate 13 peribronchial lymph nodes.

-Performed intraoperative examination.

(A1 intra-operative; A2 bronchial and vascular resection margin, A3-A5 neoformation; A6 parenchyma remote; A7-A10 lymph nodes; A7-A9 a lymph node for each monocassette).

B) a lymph node of major axis cm 0.7

C) two lymph node fragments of major axis cm 0.7

D) three lymph node fragments of major axis between cm 0.3 and cm 0.8.

E) a lymph of major axis cm 1.2

F) a reddish fragment of major axis of cm 0.7. Not isolate lymph nodes.

G) a lymph node of major axis cm 0.9

H) a lymph node of major axis cm 1.1

Histopathologic Diagnosis:

Per TSS, % signet ring unknown. (hw)

A) lung adenocarcinoma medium degree of differentiation of acinar type, with diffused production of mucus and focal aspects signet ring cell, infiltrating the connective sub pleural. Visceral pleura and bronchial resection margins free of neoplasia. Distal acinar emphysema of the remaining parenchyma. Reactive lymphadenitis with sinus histiocytosis and anthracosis of peribronchial lymph nodes. Intraoperative diagnosis(): adenocarcinoma.

B-E; G-H) reactive lymphadenitis with sinus histiocytosis, hyperplasia follicular and anthracosis
F) soft tissue free of neoplasm.

Histopathologic staging: pT2; G2; N0**Codici SNOMED:**

T-28700	M-81403	M-33900	G-CCI
T-C4340	M-77810		
T-C4365	M-77810		
T-C4310	M-77810		
T-28700	M-81403	F-C001	

ICD-0-3

adenocarcinoma, acinar 8550/3
Site: (L) lung, lower lobe C34.3

ICD-10

C34.32

hw
12/16/16

[page 2 of 2]
Submissions:

Lower lobe of the left lung , fine-needle aspiration

Cytopathological diagnosis:

highly suggestive cytological framework for adenocarcinoma with aspects such variant alveolar bronchiole mucinous .

It recommends checking intraoperative histological diagnosis confirming the hypothesis

Codici SNOMED:

T-28700

M-82503

C34-

metastatic Discrepancy		/

Source: NCI Genomic Data Commons file 00afa2f5-d368-4008-965a-2a7d3ea22a0e (CDDP-ACM1-TTP1.81CE4AA5-91EC-461C-B433-2DD631641C29.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).